Somatic mutation profile of tumor specimen TCGA-DD-A1EB-01A (aliquot TCGA-DD-A1EB-01A-11D-A12Z-10) from TCGA case TCGA-DD-A1EB, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 72.5 years (26,471 days).
Specimen TCGA-DD-A1EB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e3f8c87-7ae8-4a18-a5b7-d461980bb860.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A1EB-10A (Blood Derived Normal), aliquot TCGA-DD-A1EB-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55538027-d666-49b1-957c-b8c98d0148d9

The open-access MAF lists 198 somatic variants for this specimen: 140 protein-altering or splice-affecting, 42 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 42, Intron 7, 3'UTR 5, Splice Site 5, Nonsense Mutation 5, Splice Region 4, Frame Shift Del 3, 5'UTR 2, RNA 2, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.376T>G p.Y126D | Missense Mutation (SNP) | VAF 13/19 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886039483, CM118879, COSV52661802, COSV52809424, COSV53031989, COSV53515469; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AARS2 | c.1603G>C p.V535L | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV55113453; called by muse, mutect2, varscan2
- ABCA13 | c.13996A>G p.T4666A | Missense Mutation (SNP) | VAF 85/249 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68943733; called by muse, mutect2, varscan2
- ADH1C | c.542A>G p.Y181C | Missense Mutation (SNP) | VAF 97/138 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72463386; called by muse, mutect2, varscan2
- AGBL1 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 97/219 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV101408290; called by muse, mutect2, varscan2
- AHNAK2 | c.3730G>C p.G1244R | Missense Mutation (SNP) | VAF 50/57 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60908511; called by muse, mutect2, varscan2
- AKAP8L | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV68472877; called by muse, mutect2, varscan2
- APBA1 | c.2017G>T p.E673* | Nonsense Mutation (SNP) | VAF 35/90 reads (39%) | catalogued as COSV55222158; called by muse, mutect2, varscan2
- APPL1 | c.969G>T p.M323I | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV55699796, COSV99897292; called by muse, mutect2, varscan2
- ARHGEF6 | c.1298C>G p.S433C | Missense Mutation (SNP) | VAF 108/290 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV51687725; called by muse, mutect2, varscan2
- ARHGEF9 | c.255C>A p.D85E | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV53634847; called by muse, mutect2, varscan2
- BCAT1 | c.884T>C p.L295P | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53907753; called by muse, mutect2, varscan2
- BEND3 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs142662918, COSV64680056, COSV64681822; called by muse, mutect2, varscan2
- C3 | c.599+3A>G | Splice Region (SNP) | VAF 22/55 reads (40%) | catalogued as COSV99837418; called by muse, mutect2, varscan2
- CABLES2 | c.754C>A p.L252M | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV54155791; called by muse, mutect2, varscan2
- CDH18 | c.739G>T p.G247W | Missense Mutation (SNP) | VAF 174/304 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56903476; called by muse, mutect2, varscan2
- CDH9 | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 112/209 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as COSV50253355; called by muse, mutect2, varscan2
- CDHR2 | c.1031T>C p.M344T | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56134872; called by muse, mutect2, varscan2
- CENPE | c.6202A>G p.R2068G | Missense Mutation (SNP) | VAF 142/208 reads (68%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV54376547; called by muse, mutect2, varscan2
- CEP290 | c.3422T>C p.L1141S | Missense Mutation (SNP) | VAF 136/331 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58349027; called by muse, mutect2, varscan2
- COL10A1 | c.2035C>A p.P679T | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs138831203; called by muse, mutect2, varscan2
- COL4A5 | c.254C>A p.P85Q | Missense Mutation (SNP) | VAF 201/452 reads (44%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.776); catalogued as COSV60356517; called by muse, mutect2, varscan2
- CSMD1 | c.6274C>A p.P2092T (on ENST00000520002; = p.P2091T on NM_033225.6) | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.828); catalogued as rs1049387931, COSV59284956; called by muse, mutect2, varscan2
- CSNK1A1L | c.478T>A p.L160M | Missense Mutation (SNP) | VAF 311/689 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65789381; called by muse, mutect2, varscan2
- CTNNA3 | c.2083G>T p.D695Y | Missense Mutation (SNP) | VAF 130/323 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65521726; called by muse, mutect2, varscan2
- CTTNBP2 | c.3660C>A p.S1220R | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV50390079, COSV99354714; called by muse, mutect2, varscan2
- CUL9 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV52725688; called by muse, varscan2
- DBN1 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52787724; called by muse, mutect2, varscan2
- DDR2 | c.884G>T p.G295V | Missense Mutation (SNP) | VAF 66/289 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV63369433; called by muse, mutect2, varscan2
- DMD | c.9974+1G>T p.X3325_splice | Splice Site (SNP) | VAF 60/157 reads (38%) | catalogued as CS071228, CS098772, COSV58893333; called by muse, mutect2, varscan2
- DNAAF5 | c.1846T>C p.S616P | Missense Mutation (SNP) | VAF 122/208 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as COSV52414296; called by muse, mutect2, varscan2
- EOMES | c.1648A>T p.I550F | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV55411211; called by muse, mutect2, varscan2
- FAM180A | c.300C>A p.S100R | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV58527892; called by muse, mutect2, varscan2
- FAM186A | c.6910A>T p.I2304L | Missense Mutation (SNP) | VAF 105/263 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV59246189; called by muse, mutect2, varscan2
- FBN1 | c.3161G>A p.R1054K | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV57310001; called by muse, mutect2, varscan2
- FOXO4 | c.376C>G p.Q126E | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV58574760; called by muse, mutect2, varscan2
- FRMPD4 | c.923T>C p.L308P | Missense Mutation (SNP) | VAF 124/301 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66211592; called by muse, mutect2, varscan2
- G6PC3 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 90/257 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV52242008; called by muse, mutect2, varscan2
- GABRA4 | c.1059G>T p.R353S | Missense Mutation (SNP) | VAF 215/566 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as rs1190112652, COSV51922913, COSV51923407; called by muse, mutect2, varscan2
- GABRR2 | c.121T>C p.Y41H | Missense Mutation (SNP) | VAF 78/180 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.149); catalogued as rs1380757911, COSV68266138; called by muse, mutect2, varscan2
- GART | c.2852A>T p.D951V | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67818049; called by muse, mutect2, varscan2
- GPNMB | c.541+4G>T | Splice Region (SNP) | VAF 153/282 reads (54%) | catalogued as COSV99326170; called by muse, mutect2, varscan2
- GPR179 | c.6097G>T p.V2033L (on ENST00000621958; = p.V2032L on NM_001004334.4) | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs748614344; called by muse, mutect2, varscan2
- GRIN2B | c.2383C>T p.L795F | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV74204860; called by muse, mutect2, varscan2
- HARS2 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs752472621, COSV51226807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HMCN1 | c.2598T>G p.I866M | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54879393; called by muse, mutect2, varscan2
- HNF1A | c.761T>A p.L254Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as CM1513644, COSV57459490; called by muse, mutect2, varscan2
- IL12A | c.240G>T p.R80S | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as COSV59758805; called by muse, mutect2, varscan2
- ING2 | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV56563829, COSV56564159; called by muse, mutect2, varscan2
- ITGA10 | c.241G>C p.A81P | Missense Mutation (SNP) | VAF 136/219 reads (62%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs782165178, COSV65196144, COSV65198308; called by muse, mutect2, varscan2
- ITPRIP | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs748754399, COSV53390597; called by muse, mutect2, varscan2
- ITPRIP | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.441); catalogued as COSV53390606; called by muse, mutect2, varscan2
- KDM2A | c.444T>A p.F148L | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV67081195; called by muse, mutect2, varscan2
- KDM2A | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs774795323, COSV67081199; called by muse, mutect2, varscan2
- KDM4C | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as COSV67183854; called by muse, mutect2, varscan2
- KHDC4 | c.378A>C p.Q126H | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64164564; called by muse, mutect2, varscan2
- KIF27 | c.3701G>A p.R1234Q | Missense Mutation (SNP) | VAF 221/539 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs761847847, COSV52825381; called by muse, mutect2, varscan2
- KLHDC10 | c.565G>T p.V189L | Missense Mutation (SNP) | VAF 73/300 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.018); catalogued as COSV59050521; called by muse, mutect2, varscan2
- KRTAP10-6 | c.931G>T p.V311L | Missense Mutation (SNP) | VAF 118/258 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV59952927; called by muse, mutect2, varscan2
- LAMC1 | c.4397A>G p.K1466R | Missense Mutation (SNP) | VAF 137/494 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV51133054; called by muse, mutect2, varscan2
- MAGEL2 | c.2903G>T p.S968I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.698); catalogued as COSV58565995; called by muse, mutect2, varscan2
- MAOB | c.817C>A p.H273N | Missense Mutation (SNP) | VAF 140/420 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV65204349; called by muse, mutect2, varscan2
- MEIS2 | c.767A>T p.D256V (on ENST00000561208 / NM_170675.5; = p.D243V on NM_002399.3) | Missense Mutation (SNP) | VAF 105/225 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV54931739; called by muse, mutect2, varscan2
- MGAT4C | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.676); catalogued as COSV59830138; called by muse, mutect2, varscan2
- MICAL3 | c.5770G>A p.E1924K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52811024; called by muse, mutect2, varscan2
- MLF1 | c.756G>C p.L252F | Missense Mutation (SNP) | VAF 106/234 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100575930, COSV63032654; called by muse, mutect2, varscan2
- MMP16 | c.31C>G p.R11G | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV54152165; called by muse, mutect2, varscan2
- MTBP | c.2302A>G p.N768D | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.075); catalogued as COSV59961086; called by muse, mutect2, varscan2
- MXRA5 | c.3221A>T p.E1074V | Missense Mutation (SNP) | VAF 178/479 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as COSV54224705; called by muse, mutect2, varscan2
- MYH8 | c.5275A>C p.K1759Q | Missense Mutation (SNP) | VAF 16/433 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101238971; called by muse, mutect2
- MYO16 | c.1556G>T p.G519V | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.345); catalogued as COSV51778657; called by muse, mutect2, varscan2
- MYO18A | c.158A>G p.K53R | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV62862663; called by muse, mutect2, varscan2
- NES | c.3335G>T p.G1112V | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs771381060, COSV63960416; called by muse, varscan2
- ODAPH | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs756454916, COSV61140864, COSV61141580; called by muse, mutect2, varscan2
- OR10R2 | c.965G>T p.R322I | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.418); catalogued as COSV63768511; called by muse, mutect2
- OR1S1 | c.791T>A p.F264Y | Missense Mutation (SNP) | VAF 103/241 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV58706059; called by muse, mutect2, varscan2
- OR4K1 | c.593T>G p.M198R | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV53458896; called by muse, mutect2, varscan2
- OR4K2 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 113/390 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768493157, COSV53848239; called by muse, mutect2, varscan2
- OSBPL11 | c.592G>T p.V198F | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.113); catalogued as COSV56172460; called by muse, mutect2, varscan2
- PARM1 | c.860A>G p.Y287C | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56650376; called by muse, mutect2, varscan2
- PARS2 | c.989G>A p.G330D | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.758); catalogued as COSV64883361; called by muse, mutect2, varscan2
- PBX1 | c.540G>T p.M180I | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as rs769833066, COSV63341302; called by muse, mutect2, varscan2
- PDCD7 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); catalogued as rs766690367, COSV52599750; called by muse, mutect2, varscan2
- PDPR | c.2354G>T p.W785L | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.845); catalogued as COSV55349327; called by muse, mutect2, varscan2
- PDSS2 | c.1101C>G p.Y367* | Nonsense Mutation (SNP) | VAF 48/110 reads (44%) | catalogued as COSV64653175; called by muse, mutect2, varscan2
- PHIP | c.2770-1G>T p.X924_splice | Splice Site (SNP) | VAF 56/137 reads (41%) | catalogued as COSV51501610; called by muse, mutect2, varscan2
- PIK3C2B | c.3493C>G p.P1165A | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV65809242; called by muse, mutect2, varscan2
- PLOD2 | c.340T>C p.F114L | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV51462307; called by muse, mutect2, varscan2
- PLXNA4 | c.2667C>A p.D889E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.009); catalogued as COSV58106894; called by muse, mutect2, varscan2
- POMT2 | c.1573A>T p.K525* | Nonsense Mutation (SNP) | VAF 44/111 reads (40%) | catalogued as COSV55069758; called by muse, mutect2, varscan2
- PPP1R32 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1565138663, COSV58544118; called by muse, mutect2, varscan2
- PREB | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1326098137, COSV53204579; called by muse, mutect2, varscan2
- PREX1 | c.2329C>T p.R777W | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs371398821; called by muse, mutect2, varscan2
- PRKDC | c.2374A>G p.I792V | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV58043895; called by muse, mutect2, varscan2
- PTPRB | c.2164C>A p.H722N | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); catalogued as COSV54233174, COSV54257169; called by muse, mutect2, varscan2
- PXDNL | c.2491C>T p.P831S | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as COSV62479228; called by muse, mutect2, varscan2
- RALGDS | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as rs1391922480, COSV64425741; called by muse, mutect2, varscan2
- RGSL1 | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV54254561; called by muse, mutect2, varscan2
- RPS6KA2 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV55815972; called by muse, mutect2, varscan2
- RYR2 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1163526442, COSV63664231, COSV63701550; called by muse, mutect2, varscan2
- RYR2 | c.14383A>G p.K4795E | Missense Mutation (SNP) | VAF 121/285 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs1558462911, COSV63664244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCML1 | c.622G>T p.G208W (on ENST00000380041 / NM_001037540.3; = p.G181W on NM_006746.6) | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.405); catalogued as COSV101194001, COSV66240388; called by muse, mutect2, varscan2
- SEZ6L | c.1515G>A p.R505= | Splice Region (SNP) | VAF 34/96 reads (35%) | catalogued as COSV50658303, COSV99961164; called by muse, mutect2, varscan2
- SGCZ | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs755364582, COSV65997652; called by muse, mutect2, varscan2
- SLC27A6 | c.1776C>A p.Y592* | Nonsense Mutation (SNP) | VAF 145/387 reads (37%) | catalogued as rs1331135055, COSV52479619; called by muse, mutect2, varscan2
- SMC5 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 139/303 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.366); catalogued as COSV63191689; called by muse, mutect2, varscan2
- SMR3A | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 108/277 reads (39%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.069); catalogued as rs748957378, COSV56949714; called by muse, mutect2, varscan2
- SPTY2D1 | c.175G>C p.A59P | Missense Mutation (SNP) | VAF 98/235 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as COSV60472992; called by muse, mutect2, varscan2
- SUCO | c.1749G>C p.E583D | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV55262220; called by muse, mutect2, varscan2
- SUGT1 | c.996+1G>T p.X332_splice (on ENST00000343788 / NM_001130912.3; = p.X300_splice on NM_006704.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 43/133 reads (32%) | catalogued as COSV59421127; called by muse, mutect2, varscan2
- TBC1D4 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV66487777; called by muse, mutect2, varscan2
- TCF25 | c.700C>G p.L234V | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV54524571; called by muse, mutect2, varscan2
- TECTB | c.473A>G p.N158S | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs538658987, COSV65594729; called by muse, mutect2, varscan2
- TEX35 | c.342-1G>C p.X114_splice | Splice Site (SNP) | VAF 22/99 reads (22%) | catalogued as COSV51103300; called by muse, mutect2, varscan2
- TGIF2LX | c.492G>T p.K164N | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.045); catalogued as COSV52213391, COSV52215223; called by muse, mutect2, varscan2
- TRMU | c.1018+1G>A p.X340_splice | Splice Site (SNP) | VAF 34/46 reads (74%) | catalogued as COSV51989539; called by muse, mutect2, varscan2
- TTN | c.46024G>C p.V15342L (on ENST00000591111; = p.V7918L on NM_003319.4) | Missense Mutation (SNP) | VAF 71/139 reads (51%) | PolyPhen benign (0.022); catalogued as COSV59901820; called by muse, mutect2, varscan2
- UNC13D | c.679C>A p.R227S | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); catalogued as COSV52883108, COSV52884757; called by muse, mutect2, varscan2
- USP48 | c.2932G>A p.D978N | Missense Mutation (SNP) | VAF 95/273 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV57607415; called by muse, mutect2, varscan2
- VGLL1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65702931; called by muse, mutect2, varscan2
- VRTN | c.983dup p.V329Rfs*25 | Frame Shift Ins (INS) | VAF 6/20 reads (30%) | catalogued as rs749358571; called by mutect2, varscan2
- ZFP2 | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63724691; called by muse, mutect2, varscan2
- ZNF407 | c.3971G>A p.G1324D | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV55243661; called by muse, mutect2, varscan2
- ZNF474 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV56945351; called by muse, mutect2, varscan2
- ZNF611 | c.1175A>G p.H392R | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs749883716, COSV60539588; called by muse, mutect2, varscan2
- ZNF808 | c.1825G>T p.A609S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs775343092, COSV63118764; called by muse, mutect2, varscan2
- ZUP1 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 26/288 reads (9%) | catalogued as COSV63943974; called by muse, mutect2
- ANKRD20A1 | c.1916A>T p.D639V | Missense Mutation (SNP) | VAF 246/894 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, varscan2
- ARHGEF40 | c.4395A>C p.E1465D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2
- ARHGEF5 | c.4064G>T p.C1355F | Missense Mutation (SNP) | VAF 191/1150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CMYA5 | c.3351_3365del p.Y1118_E1122del | In Frame Del (DEL) | VAF 59/202 reads (29%) | called by mutect2, varscan2
- COL10A1 | c.2036C>A p.P679Q | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPNMB | c.541+5G>T | Splice Region (SNP) | VAF 151/282 reads (54%) | called by muse, mutect2, varscan2
- HNF1A | c.141_144del p.E48Pfs*106 | Frame Shift Del (DEL) | VAF 28/78 reads (36%) | called by mutect2, varscan2
- KLHDC10 | c.566T>A p.V189E | Missense Mutation (SNP) | VAF 70/299 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MPEG1 | c.1200_1201insC p.E401Rfs*9 | Frame Shift Ins (INS) | VAF 34/105 reads (32%) | called by mutect2, varscan2
- NINL | c.2558G>A p.C853Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- NPAS2 | c.362del p.P121Rfs*10 | Frame Shift Del (DEL) | VAF 87/187 reads (47%) | called by mutect2, varscan2
- TTC14 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 84/206 reads (41%) | called by mutect2, varscan2
- YIPF1 | c.33A>T p.E11D | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADGRG4 | c.8676T>C p.S2892= | Silent (SNP) | VAF 156/438 reads (36%) | catalogued as COSV54950181; called by muse, mutect2, varscan2
- ANK2 | c.8541A>T p.S2847= | Silent (SNP) | VAF 70/192 reads (36%) | catalogued as COSV52147455; called by muse, mutect2, varscan2
- ARHGEF5 | c.4065C>T p.C1355= | Silent (SNP) | VAF 196/1161 reads (17%) | called by muse, mutect2, varscan2
- ATXN3L | c.915C>A p.G305= | Silent (SNP) | VAF 190/413 reads (46%) | catalogued as COSV66075273; called by muse, mutect2, varscan2
- BPIFA1 | c.180G>T p.L60= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV62823924; called by muse, mutect2, varscan2
- CASK | c.1518A>G p.K506= | Silent (SNP) | VAF 147/373 reads (39%) | catalogued as COSV59362179; called by muse, mutect2, varscan2
- CEP295NL | c.1746C>T p.D582= | Silent (SNP) | VAF 115/536 reads (21%) | catalogued as rs571031295, COSV53159874; called by muse, mutect2, varscan2
- CLDN1 | c.360C>A p.V120= | Silent (SNP) | VAF 48/141 reads (34%) | catalogued as COSV55043525; called by muse, mutect2, varscan2
- DCAF8L1 | c.936C>T p.F312= | Silent (SNP) | VAF 56/165 reads (34%) | catalogued as COSV71595137, COSV71595193; called by muse, mutect2, varscan2
- DSTYK | c.153C>T p.F51= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs932143976, COSV65685429; called by muse, varscan2
- ERCC8 | c.444T>C p.H148= | Silent (SNP) | VAF 114/287 reads (40%) | catalogued as COSV54014632; called by muse, mutect2, varscan2
- GANAB | c.114T>C p.F38= | Silent (SNP) | VAF 77/174 reads (44%) | catalogued as COSV60462113; called by muse, mutect2, varscan2
- GRIK4 | c.1866T>C p.S622= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV70799985; called by muse, mutect2, varscan2
- HTATSF1 | c.516T>G p.L172= | Silent (SNP) | VAF 225/531 reads (42%) | catalogued as COSV54477485; called by muse, mutect2, varscan2
- IDH3A | c.486T>C p.D162= | Silent (SNP) | VAF 58/95 reads (61%) | catalogued as COSV55112054; called by muse, mutect2, varscan2
- ITPRID1 | c.2793G>T p.R931= | Silent (SNP) | VAF 191/405 reads (47%) | catalogued as rs1453424881, COSV60070503; called by muse, mutect2, varscan2
- KCTD8 | c.1350C>T p.I450= | Silent (SNP) | VAF 92/197 reads (47%) | catalogued as COSV63585641; called by muse, mutect2, varscan2
- LRCH3 | c.1737T>C p.A579= | Silent (SNP) | VAF 86/229 reads (38%) | catalogued as rs1339289079, COSV58389247; called by muse, mutect2, varscan2
- MAEL | c.681G>A p.L227= | Silent (SNP) | VAF 94/357 reads (26%) | catalogued as COSV63112295; called by muse, mutect2, varscan2
- MCCC1 | c.1314C>G p.V438= | Silent (SNP) | VAF 80/174 reads (46%) | catalogued as rs774243822, COSV55606540; called by muse, mutect2, varscan2
- MEF2C | c.855C>A p.S285= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV60925945; called by muse, mutect2, varscan2
- MGA | c.8847G>A p.K2949= (on ENST00000219905 / NM_001164273.1; = p.K2740= on NM_001080541.2) | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV54949369; called by muse, mutect2, varscan2
- MYO18B | c.7668T>C p.D2556= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV59126218; called by muse, varscan2
- NAA15 | c.942A>G p.L314= | Silent (SNP) | VAF 87/194 reads (45%) | catalogued as COSV56717784; called by muse, mutect2, varscan2
- NBEA | c.1638G>T p.L546= | Silent (SNP) | VAF 62/166 reads (37%) | catalogued as COSV59762191; called by muse, mutect2, varscan2
- OTOGL | c.6519A>G p.V2173= (on ENST00000547103; = p.V2164= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 69/187 reads (37%) | catalogued as rs370122451; called by muse, mutect2, varscan2
- PCDHB11 | c.1449C>T p.N483= | Silent (SNP) | VAF 60/151 reads (40%) | catalogued as rs1281698776, COSV61309938, COSV61314106; called by muse, mutect2, varscan2
- PCNA | c.678A>G p.T226= | Silent (SNP) | VAF 97/224 reads (43%) | catalogued as COSV52531702; called by muse, mutect2, varscan2
- PDGFD | c.219C>T p.Y73= | Silent (SNP) | VAF 150/388 reads (39%) | catalogued as COSV56369265; called by muse, mutect2, varscan2
- PLAA | c.951G>T p.L317= | Silent (SNP) | VAF 111/313 reads (35%) | catalogued as COSV68304546; called by muse, mutect2, varscan2
- PLCXD3 | c.768G>A p.V256= | Silent (SNP) | VAF 147/264 reads (56%) | catalogued as COSV60605174; called by muse, mutect2, varscan2
- RBKS | c.481T>C p.L161= | Silent (SNP) | VAF 44/142 reads (31%) | catalogued as rs745591332, COSV56220363; called by muse, mutect2, varscan2
- RTN1 | c.1848C>A p.T616= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV50719022; called by muse, mutect2, varscan2
- SIL1 | c.855A>G p.A285= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV54528222; called by muse, mutect2, varscan2
- SIRT4 | c.51C>T p.I17= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs199859894, COSV52540138; called by muse, mutect2, varscan2
- SPATA19 | c.240C>A p.G80= | Silent (SNP) | VAF 82/196 reads (42%) | catalogued as COSV54482631; called by muse, mutect2, varscan2
- SSR2 | c.177A>G p.L59= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as rs1452078676, COSV55302855; called by muse, mutect2, varscan2
- TACC2 | c.4521G>T p.R1507= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs1290319071, COSV57747078; called by muse, mutect2, varscan2
- UNKL | c.1578C>T p.S526= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1162742912, COSV50189815; called by muse, mutect2, varscan2
- UPP1 | c.798C>T p.A266= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs1044090475, COSV57977025; called by muse, mutect2, varscan2
- XPO6 | c.3087G>T p.V1029= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV58963718; called by muse, mutect2, varscan2
- ZDHHC3 | c.899G>A p.*300= (on ENST00000424952 / NM_001135179.2; = p.*328= on NM_016598.3) | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as COSV56100626; called by muse, mutect2, varscan2
- CRIP3 | c.*111G>C | 3'UTR (SNP) | VAF 56/170 reads (33%) | catalogued as COSV51482936; called by muse, mutect2, varscan2
- CRYM-AS1 | n.396A>G | RNA (SNP) | VAF 57/172 reads (33%) | called by muse, mutect2, varscan2
- EMD | c.449+21G>A | Intron (SNP) | VAF 53/137 reads (39%) | called by muse, mutect2, varscan2
- EMD | c.449+22G>T | Intron (SNP) | VAF 53/139 reads (38%) | called by muse, mutect2, varscan2
- ERCC8 | c.-11G>C | 5'UTR (SNP) | VAF 26/48 reads (54%) | catalogued as COSV99410818; called by muse, mutect2, varscan2
- KAT5 | c.12+49A>G | Intron (SNP) | VAF 30/84 reads (36%) | catalogued as rs755559349, COSV58062202; called by muse, mutect2, varscan2
- KLHL34 | c.-136T>G | 5'UTR (SNP) | VAF 24/63 reads (38%) | catalogued as COSV101070026; called by muse, mutect2
- LAIR1 | c.454+16C>T | Intron (SNP) | VAF 44/124 reads (35%) | catalogued as rs750197955; called by muse, mutect2, varscan2
- NCR2 | c.531-33G>T | Intron (SNP) | VAF 24/57 reads (42%) | catalogued as COSV66100118; called by muse, mutect2, varscan2
- PABPC3 | c.*242A>T | 3'UTR (SNP) | VAF 45/97 reads (46%) | catalogued as COSV99880197; called by muse, mutect2, varscan2
- PDP1 | c.*1535C>G | 3'UTR (SNP) | VAF 101/208 reads (49%) | catalogued as COSV99893071; called by muse, mutect2, varscan2
- PIPSL | n.1938G>A | RNA (SNP) | VAF 113/259 reads (44%) | called by muse, mutect2, varscan2
- SH2D1B | c.*5A>T | 3'UTR (SNP) | VAF 75/237 reads (32%) | catalogued as COSV100854888; called by muse, mutect2
- SRSF1 | c.552+35A>G | Intron (SNP) | VAF 35/103 reads (34%) | catalogued as COSV51964213; called by muse, mutect2, varscan2
- ZNF805 | c.*6899G>A | 3'UTR (SNP) | VAF 24/74 reads (32%) | catalogued as rs138744456; called by muse, mutect2, varscan2
- ZSCAN32 | c.915-216A>C | Intron (SNP) | VAF 108/273 reads (40%) | catalogued as COSV59234122; called by muse, varscan2
